ALCHEMIST case ALCH-AEOW — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/b969ac37-6346-4794-9706-90cacbad8d6c

Demographics
Sex at birth: male.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: Age at diagnosis: 60.5 years (22,092 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-AEOW-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-AEOW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-AEOW-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 49; Percent tumor nuclei: 42; Percent normal cells: 17; Percent necrosis: 7; Percent stromal cells: 27; Percent lymphocyte infiltration: 44; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 5.
